Somatic mutation profile of tumor specimen TARGET-30-PAPYNZ-01A (aliquot TARGET-30-PAPYNZ-01A-01D) from TARGET case TARGET-30-PAPYNZ, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 2.8 years (1,024 days).
Specimen TARGET-30-PAPYNZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fab8c0f4-d28f-4b3b-a4a8-fa8757a26fe4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPYNZ-10A (Blood Derived Normal), aliquot TARGET-30-PAPYNZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dcef144d-06d5-4e46-be65-c63683883cb5

The open-access MAF lists 17 somatic variants for this specimen: 16 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 15, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLCB4 | c.1888G>T p.D630Y | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568763104, COSV53793606, COSV53801055; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACAN | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs564289325, COSV61355619; called by mutect2, varscan2
- AQP4 | c.192G>T p.K64N | Missense Mutation (SNP) | VAF 90/304 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV67218241; called by muse, varscan2
- C2orf42 | c.630G>T p.Q210H | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.719); catalogued as COSV52448809; called by muse, mutect2, varscan2
- COL28A1 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs371960243; called by mutect2, varscan2
- CYP17A1 | c.473C>A p.A158D | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.703); catalogued as COSV64004706; called by muse, mutect2, varscan2
- DNAH5 | c.8614G>T p.V2872L | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV54203470; called by muse, mutect2, varscan2
- DSG4 | c.1802C>T p.A601V | Missense Mutation (SNP) | VAF 74/132 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs369630802; called by mutect2, varscan2
- EIF2B4 | c.167C>A p.A56E | Missense Mutation (SNP) | VAF 38/260 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV52006361, COSV52007269; called by muse, varscan2
- EPPK1 | c.3058G>A p.V1020M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as rs782175370, COSV73260790; called by muse, mutect2, varscan2
- ITPKB | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); catalogued as rs751539212, COSV55257112; called by mutect2, varscan2
- KMT2A | c.6772C>A p.Q2258K | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as CM1513742, COSV63281841; called by muse, mutect2, varscan2
- MAST2 | c.2477A>C p.E826A | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.297); catalogued as COSV63616075; called by muse, mutect2, varscan2
- RYR1 | c.14861A>G p.D4954G | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV62088657; called by muse, mutect2, varscan2
- XIRP2 | c.1753G>T p.E585* (on ENST00000628543; = p.E760* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 34/70 reads (49%) | catalogued as COSV54682058; called by mutect2, varscan2
- ADGRV1 | c.16244C>A p.T5415K | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.457); called by muse, mutect2
- IL12A | c.414C>T p.F138= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV59758720; called by mutect2, varscan2
